Somatic mutation profile of tumor specimen TCGA-VQ-A8PP-01A (aliquot TCGA-VQ-A8PP-01A-21D-A410-08) from TCGA case TCGA-VQ-A8PP, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 76.0 years (27,774 days).
Specimen TCGA-VQ-A8PP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70734750-7b9f-4837-a81e-46155f376d96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PP-10A (Blood Derived Normal), aliquot TCGA-VQ-A8PP-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71de529d-f43d-46bf-9ae9-91bce54f2c7c

The open-access MAF lists 1,719 somatic variants for this specimen: 1,320 protein-altering or splice-affecting, 361 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 869, Silent 361, Frame Shift Del 320, Frame Shift Ins 47, Nonsense Mutation 40, Splice Site 22, Intron 21, In Frame Del 11, 3'UTR 7, Splice Region 7, RNA 3, 5'Flank 3.

Variants (750 of 1,719; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC127029.3 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs137853223, CM970646, COSV100033198; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS13 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs121908471, CM012889, COSV63021688; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGXT | c.33del p.K12Rfs*34 | Frame Shift Del (DEL) | VAF 14/23 reads (61%) | catalogued as rs180177201, CM056286; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AHDC1 | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as rs1165205177, COSV99898973, COSV99899324; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BAG3 | c.72del p.G25Dfs*186 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs727502897; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- BRCA2 | c.3847_3848del p.V1283Kfs*2 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | catalogued as rs80359405; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 29/54 reads (54%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2D | c.1940dup p.P648Tfs*2 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | catalogued as rs770315135; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); catalogued as rs121913528, COSV55499283, COSV55796966; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MCPH1 | c.321del p.K107Nfs*39 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs759663956; ClinVar: pathogenic; called by mutect2, varscan2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by pindel, varscan2
- MLH1 | c.1489del p.R497Gfs*11 | Frame Shift Del (DEL) | VAF 60/250 reads (24%) | catalogued as rs63750855, COSV51623024; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 30/90 reads (33%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- OPLAH | c.2608dup p.H870Pfs*92 | Frame Shift Ins (INS) | VAF 10/38 reads (26%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 38/90 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PROK2 | c.297del p.F99Lfs*28 (on ENST00000295619 / NM_001126128.2; = p.F78Lfs*28 on NM_021935.4) | Frame Shift Del (DEL) | VAF 23/64 reads (36%) | catalogued as rs768413190; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- SACS | c.8793del p.K2931Nfs*22 | Frame Shift Del (DEL) | VAF 35/143 reads (24%) | catalogued as rs767871841, CD056854; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SDHA | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); catalogued as rs397514541, CM163827, COSV53767867, COSV53772354; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2ML1 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.333); catalogued as rs199779757, COSV55295017; called by muse, mutect2, varscan2
- A2ML1 | c.2495A>G p.Y832C | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1275324253, COSV100228608; called by muse, mutect2, varscan2
- A3GALT2 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as COSV100378143; called by muse, mutect2, varscan2
- AASDH | c.1319del p.L440Wfs*43 | Frame Shift Del (DEL) | VAF 25/54 reads (46%) | catalogued as rs770970036; called by mutect2, varscan2
- AASS | c.2027T>C p.V676A | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV100741701; called by muse, mutect2, varscan2
- ABCA12 | c.4604A>G p.H1535R (on ENST00000272895 / NM_173076.3; = p.H1217R on NM_015657.3) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99788734; called by muse, mutect2, varscan2
- ABCA2 | c.5318A>G p.Y1773C (on ENST00000614293; = p.Y1743C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99687066; called by muse, mutect2, varscan2
- ABCA2 | c.2584G>A p.V862M (on ENST00000614293; = p.V832M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99687067; called by muse, mutect2, varscan2
- ABCB4 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.01); catalogued as COSV99709878; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC8 | c.1011+2T>C p.X337_splice | Splice Site (SNP) | VAF 19/103 reads (18%) | catalogued as COSV100216762; called by muse, mutect2, varscan2
- ABHD16A | c.189G>A p.L63= | Splice Region (SNP) | VAF 9/32 reads (28%) | catalogued as COSV101012184; called by muse, mutect2, varscan2
- AC100868.1 | c.978G>T p.M326I | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV51837927, COSV99225432; called by muse, mutect2
- AC231657.3 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); catalogued as rs1476060327, COSV100540131; called by muse, mutect2, varscan2
- ACAD11 | c.886A>G p.R296G | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.839); catalogued as COSV99391681; called by muse, mutect2, varscan2
- ACOT13 | c.383_386del p.L128* | Frame Shift Del (DEL) | VAF 39/104 reads (38%) | catalogued as rs746562084; called by mutect2, pindel, varscan2
- ACSL3 | c.805+2T>C p.X269_splice | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as COSV62484427; called by muse, mutect2, varscan2
- ACTL7A | c.1068dup p.N357Efs*16 | Frame Shift Ins (INS) | VAF 24/89 reads (27%) | catalogued as rs759952745; called by mutect2, pindel, varscan2
- ACTR1B | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs755905355, COSV100008012; called by muse, mutect2, varscan2
- ACTR5 | c.1567-2A>G p.X523_splice | Splice Site (SNP) | VAF 15/77 reads (19%) | catalogued as rs890559732, COSV99709921; called by muse, mutect2, varscan2
- ADAM15 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.547); catalogued as rs779369135, COSV55126822; called by muse, mutect2, varscan2
- ADAM19 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs755386906, COSV99976364; called by muse, mutect2, varscan2
- ADAM29 | c.1871A>T p.N624I | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV100821927; called by muse, mutect2, varscan2
- ADAM33 | c.1312-2A>C p.X438_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100597718; called by muse, mutect2, varscan2
- ADAM7 | c.2002+1G>A p.X668_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99443186; called by muse, mutect2, varscan2
- ADAMTS10 | c.883A>G p.T295A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99546559; called by muse, mutect2, varscan2
- ADAMTS2 | c.2210-2del p.X737_splice | Splice Site (DEL) | VAF 8/25 reads (32%) | catalogued as rs1219329381; called by mutect2, pindel
- ADAR | c.2314G>A p.V772I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763229776, COSV99425614; called by muse, mutect2, varscan2
- ADCY1 | c.1536G>A p.M512I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV99811442; called by muse, mutect2, varscan2
- ADCY10 | c.1808A>G p.Q603R | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as rs772108925, COSV100896627; called by muse, mutect2, varscan2
- ADCY5 | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs766925631, COSV59200161; called by muse, mutect2, varscan2
- ADGRB1 | c.3169G>A p.G1057S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV60098339; called by muse, mutect2, varscan2
- ADGRB2 | c.4307C>T p.P1436L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0.07); catalogued as COSV99925803; called by muse, mutect2, varscan2
- ADGRG4 | c.506G>A p.S169N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.063); catalogued as rs780690525, COSV54961493; called by muse, mutect2, varscan2
- ADGRG5 | c.608del p.G203Afs*62 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | catalogued as rs750862917; called by mutect2, pindel, varscan2
- ADGRL1 | c.2135C>T p.A712V (on ENST00000340736 / NM_001008701.3; = p.A707V on NM_014921.5) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100529317; called by muse, mutect2, varscan2
- ADGRV1 | c.15933A>C p.K5311N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV101315572; called by muse, mutect2, varscan2
- ADNP | c.2372C>T p.A791V | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV100823656; called by muse, mutect2, varscan2
- AFF3 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770557623, COSV57854272; called by muse, mutect2, varscan2
- AGBL1 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as rs376573682; called by muse, mutect2, varscan2
- AGL | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as rs557516658, COSV99648638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGPAT5 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs765753866, COSV53449261; called by muse, varscan2
- AGRN | c.2996C>T p.A999V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1272652643; called by muse, mutect2
- AHCTF1 | c.109C>T p.R37* (on ENST00000366508; = p.R11* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as rs866640499, COSV100403238; called by muse, mutect2, varscan2
- AHNAK | c.5242G>A p.V1748M | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as COSV99946016; called by muse, mutect2, varscan2
- AHNAK2 | c.12239T>C p.L4080P | Missense Mutation (SNP) | VAF 101/286 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100316123; called by muse, mutect2, varscan2
- AKAP11 | c.1532C>T p.T511I | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs143140014, COSV99213619; called by muse, mutect2, varscan2
- AKTIP | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV100289678; called by muse, mutect2, varscan2
- AL136295.1 | c.2015C>T p.T672I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV55779126; called by muse, mutect2, varscan2
- AL592490.1 | c.2795T>G p.L932R | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101308121; called by muse, mutect2, varscan2
- ALDH16A1 | c.1039del p.A347Lfs*155 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | catalogued as rs1368010977; called by mutect2, pindel, varscan2
- ALG10 | c.904del p.S302Pfs*17 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | catalogued as rs779782051; called by mutect2, varscan2
- ALG13 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1064796372, COSV99321779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALMS1 | c.8068C>T p.P2690S | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as rs868395190, COSV52506909; called by muse, mutect2, varscan2
- ALOX12B | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs1274525093, COSV100046719; called by muse, mutect2, varscan2
- ALPL | c.581del p.P194Lfs*4 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs758124823, CM084852; called by pindel, varscan2
- AMPD3 | c.47A>G p.Q16R (on ENST00000396553 / NM_001025389.2; = p.Q25R on NM_000480.3) | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV101158105; called by muse, mutect2, varscan2
- ANKEF1 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 31/85 reads (36%) | catalogued as COSV101000993; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7092A>G p.I2364M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.278); catalogued as COSV99782337; called by muse, mutect2, varscan2
- ANKK1 | c.917G>T p.R306M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV100392727; called by muse, mutect2, varscan2
- ANKK1 | c.1670A>G p.D557G | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100392729; called by muse, mutect2
- ANKRD11 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56361220; called by muse, mutect2, varscan2
- ANKRD27 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.166); catalogued as rs376471915; called by muse, mutect2, varscan2
- ANKRD49 | c.208del p.M70Wfs*32 | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | catalogued as rs753570186; called by mutect2, varscan2
- ANKRD53 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.188); catalogued as COSV99721263; called by muse, mutect2, varscan2
- AP3B2 | c.2668G>A p.G890R (on ENST00000261722; = p.G884R on NM_004644.5) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.403); catalogued as rs760395320, COSV99916147; called by muse, mutect2, varscan2
- AP4M1 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.565); catalogued as rs771293623, COSV57997550; called by muse, mutect2, varscan2
- APBA1 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV99595568; called by muse, mutect2
- APCDD1L | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.866); catalogued as COSV100953938; called by muse, mutect2, varscan2
- APIP | c.548A>G p.E183G | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV99551447; called by muse, mutect2, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs546686089; called by mutect2, varscan2
- APOB | c.13171C>G p.P4391A | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); catalogued as COSV99264082; called by muse, mutect2, varscan2
- AQP2 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1253955671, COSV99550753; called by muse, mutect2, varscan2
- ARFGEF3 | c.3835A>G p.T1279A | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as COSV99292625; called by muse, mutect2, varscan2
- ARGLU1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs760481710, COSV100639747; called by muse, mutect2, varscan2
- ARHGAP20 | c.2533T>G p.C845G | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs752102623, COSV99503290; called by muse, mutect2, varscan2
- ARHGEF18 | c.1756G>A p.A586T (on ENST00000359920 / NM_001130955.2; = p.A482T on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs776929047, COSV60467331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF26 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1420766234, COSV100726419, COSV62843950; called by muse, mutect2, varscan2
- ARHGEF26 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1008769557, COSV100726420; called by muse, mutect2, varscan2
- ART5 | c.257del p.P86Lfs*9 | Frame Shift Del (DEL) | VAF 9/83 reads (11%) | catalogued as COSV51707195; called by mutect2, pindel, varscan2
- ASIC3 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52502190; called by muse, mutect2
- ASPRV1 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated, low confidence (0.43); PolyPhen possibly damaging (0.855); catalogued as COSV100208419; called by muse, mutect2, varscan2
- ATAT1 | c.446T>C p.V149A | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs769722861, COSV99457590; called by muse, mutect2, varscan2
- ATM | c.640T>C p.S214P | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs747053710, CD961792, COSV53739773, COSV53739922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10A | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV63520383; called by muse, varscan2
- ATP13A1 | c.2630T>C p.V877A | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV99365738; called by muse, mutect2, varscan2
- ATP13A2 | c.217del p.V73Cfs*20 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | catalogued as rs1389678247; called by mutect2, pindel, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- ATRN | c.2197A>C p.S733R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV99496732; called by muse, mutect2
- ATXN2L | c.2087C>T p.P696L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.168); catalogued as rs747692323, COSV100293870; called by muse, mutect2, varscan2
- AZU1 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs754040928, COSV52141824; called by muse, mutect2
- B3GALNT1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.446); catalogued as rs143966469; called by muse, mutect2, varscan2
- B4GALNT2 | c.932A>G p.Y311C | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100302452; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99133766; called by muse, mutect2, varscan2
- BAIAP3 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs145056617; called by muse, mutect2, varscan2
- BCCIP | c.494T>G p.L165R | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99501433; called by muse, mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs752427670; called by mutect2, varscan2
- BEND5 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1388977229, COSV100884091; called by muse, mutect2, varscan2
- BICDL1 | c.1383G>T p.K461N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV99985924, COSV99986005; called by muse, mutect2
- BMP6 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99306443; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BNC1 | c.225del p.M76Cfs*14 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs751941533; called by mutect2, pindel, varscan2
- BPIFB4 | c.302del p.G101Afs*132 | Frame Shift Del (DEL) | VAF 17/110 reads (15%) | catalogued as rs913393654; called by pindel, varscan2
- BPTF | c.4339A>T p.T1447S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV100074293; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 10/32 reads (31%) | catalogued as rs749043197; called by mutect2, varscan2
- BRIP1 | c.344C>A p.P115H | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as rs1555617800, COSV52000418, COSV99369490; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRS3 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 25/38 reads (66%) | catalogued as COSV65710876; called by muse, mutect2, varscan2
- BSN | c.6503G>A p.G2168E | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99607538; called by muse, mutect2, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 40/132 reads (30%) | catalogued as rs752512017; called by mutect2, varscan2
- BTNL9 | c.1478G>A p.G493D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.688); catalogued as COSV100576104; called by muse, mutect2
- C19orf57 | c.463del p.L155Sfs*188 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | catalogued as rs1462893584; called by mutect2, pindel, varscan2
- C1GALT1 | c.641T>C p.V214A | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV99777510; called by muse, mutect2, varscan2
- C22orf23 | c.21G>T p.M7I | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99970099; called by muse, mutect2, varscan2
- C4orf33 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV99828852; called by muse, mutect2, varscan2
- C4orf33 | c.523A>C p.N175H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs140576328, COSV99828855; called by muse, mutect2, varscan2
- C9orf131 | c.1465G>T p.G489* | Nonsense Mutation (SNP) | VAF 11/112 reads (10%) | catalogued as COSV100397964, COSV56610626; called by muse, mutect2
- CA2 | c.440del p.L147* | Frame Shift Del (DEL) | VAF 29/126 reads (23%) | catalogued as rs763603775; called by mutect2, pindel, varscan2
- CACNA1A | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64211255; called by muse, mutect2, varscan2
- CACNA1E | c.4745G>A p.R1582H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62393577; called by muse, mutect2, varscan2
- CACNA2D3 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99868434, COSV99871154; called by muse, mutect2, varscan2
- CACNG6 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.968); catalogued as COSV99403302, COSV99403386; called by muse, mutect2, varscan2
- CACNG8 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs750723024, COSV54413877; called by muse, mutect2, varscan2
- CACTIN | c.2189A>G p.Y730C | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as rs1279019288, COSV99698343; called by muse, mutect2, varscan2
- CAMK1G | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs374701638; called by muse, mutect2, varscan2
- CAMSAP1 | c.4735G>A p.A1579T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1267363192, COSV56718227; called by muse, mutect2
- CAMSAP2 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1278305730, COSV52675859; called by muse, mutect2, varscan2
- CAMSAP3 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.194); catalogued as COSV99350016; called by muse, mutect2, varscan2
- CAMTA2 | c.3190-2A>G p.X1064_splice | Splice Site (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99236253; called by muse, mutect2, varscan2
- CAND2 | c.1151G>A p.R384H (on ENST00000456430 / NM_001162499.2; = p.R291H on NM_012298.3) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1382986188, COSV99928722; called by muse, mutect2
- CANX | c.533A>G p.Q178R | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as rs1215986273, COSV99910281; called by muse, varscan2
- CAPN15 | c.2206C>T p.R736* | Nonsense Mutation (SNP) | VAF 32/143 reads (22%) | catalogued as rs532420248, COSV54837172; called by muse, mutect2, varscan2
- CAPN5 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs782484868, COSV99581840; called by muse, mutect2, varscan2
- CAPN7 | c.506A>C p.K169T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99512600; called by muse, mutect2, varscan2
- CARD11 | c.3175G>A p.G1059S | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376446854, COSV67797190; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 23/71 reads (32%) | catalogued as rs765105588; called by mutect2, varscan2
- CASS4 | c.983G>A p.S328N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs772751260, COSV100824566; called by muse, mutect2, varscan2
- CASZ1 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as rs1361254433, COSV59736328; called by muse, mutect2, varscan2
- CBFA2T3 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs764998500, COSV51928371; called by muse, varscan2
- CBFA2T3 | c.976C>A p.R326S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.714); catalogued as COSV99241221; called by muse, varscan2
- CCDC142 | c.136T>G p.W46G | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.051); catalogued as COSV99281969; called by muse, mutect2, varscan2
- CCDC146 | c.654A>C p.E218D | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.379); catalogued as COSV99592261; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC47 | c.293A>G p.D98G | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV99854042; called by muse, mutect2, varscan2
- CCDC70 | c.291G>A p.W97* | Nonsense Mutation (SNP) | VAF 27/133 reads (20%) | catalogued as COSV99665300, COSV99665313; called by muse, mutect2, varscan2
- CCK | c.293T>G p.M98R | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100588994; called by muse, mutect2, varscan2
- CCNA1 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as COSV99714389; called by muse, mutect2, varscan2
- CCNYL1 | c.995A>G p.K332R (on ENST00000295414 / NM_001330218.2; = p.K262R on NM_152523.2) | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV99775722; called by muse, mutect2, varscan2
- CD109 | c.3680G>A p.R1227H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.07); catalogued as rs775503130, COSV54650900, COSV54657900; called by muse, mutect2, varscan2
- CD163L1 | c.2920T>A p.S974T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.647); catalogued as COSV100549780; called by muse, mutect2, varscan2
- CD163L1 | c.2185A>G p.R729G | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs148882900; called by muse, mutect2, varscan2
- CD3E | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs563868055, COSV62346096; called by muse, mutect2, varscan2
- CD80 | c.363T>A p.Y121* | Nonsense Mutation (SNP) | VAF 26/110 reads (24%) | catalogued as COSV99958166; called by muse, mutect2, varscan2
- CDC23 | c.1002C>A p.C334* | Nonsense Mutation (SNP) | VAF 5/95 reads (5%) | catalogued as COSV101203090; called by muse, mutect2
- CDC42BPB | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775265; called by muse, mutect2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH17 | c.1552-1G>T p.X518_splice | Splice Site (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99217019; called by muse, mutect2, varscan2
- CDH20 | c.806A>G p.D269G | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99404560; called by muse, mutect2, varscan2
- CDH3 | c.2225C>T p.P742L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99867740; called by muse, mutect2
- CEBPA | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100204435, COSV57196348, COSV57198506; called by muse, mutect2
- CEBPZ | c.1428del p.D477Mfs*11 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs763090473; called by mutect2, varscan2
- CELSR1 | c.8536G>A p.V2846I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs141057075; called by muse, mutect2, varscan2
- CELSR1 | c.4700C>T p.A1567V | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99417121; called by muse, mutect2, varscan2
- CELSR2 | c.6369C>A p.H2123Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.137); catalogued as COSV99603245; called by muse, mutect2, varscan2
- CEMIP | c.3581C>A p.P1194Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99586257; called by muse, mutect2, varscan2
- CEMIP2 | c.1199T>C p.I400T | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV100987258; called by muse, mutect2
- CENPE | c.7354C>T p.P2452S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV99477195; called by muse, mutect2, varscan2
- CENPU | c.380del p.K127Sfs*31 | Frame Shift Del (DEL) | VAF 24/114 reads (21%) | catalogued as rs34873798; called by mutect2, pindel, varscan2
- CEP135 | c.779A>G p.E260G | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99954197; called by muse, mutect2, varscan2
- CEP164 | c.1742T>C p.V581A | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99632701; called by muse, mutect2, varscan2
- CFAP52 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs139653833; called by muse, mutect2, varscan2
- CFAP54 | c.5302A>C p.I1768L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.029); catalogued as COSV100733002; called by muse, varscan2
- CFAP97 | c.306del p.K102Nfs*23 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs1305639008; called by mutect2, pindel, varscan2
- CHD1 | c.629del p.K210Rfs*39 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as COSV52337505; called by mutect2, pindel, varscan2
- CHD3 | c.3559C>T p.R1187C | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57878774; called by muse, mutect2, varscan2
- CHD9 | c.7893del p.R2632Dfs*28 (on ENST00000398510 / NM_001382353.1; = p.R2616Dfs*28 on NM_025134.7) | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | catalogued as rs1567694162; called by mutect2, pindel, varscan2
- CHL1 | c.3550G>A p.A1184T (on ENST00000397491 / NM_001253387.1; = p.A1200T on NM_006614.4) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV99850373; called by muse, mutect2, varscan2
- CHRM2 | c.974T>C p.I325T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.3); catalogued as COSV100280850; called by muse, mutect2, varscan2
- CHRM3 | c.1607A>G p.N536S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99697692; called by muse, varscan2
- CHRNA10 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99167129; called by muse, mutect2, varscan2
- CHRNA7 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.094); catalogued as rs773777508; called by mutect2, varscan2
- CHST1 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as rs747837712, COSV100346061, COSV57325116; called by muse, mutect2, varscan2
- CHST5 | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV60337403, COSV60338096; called by muse, mutect2, varscan2
- CIART | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as COSV99290150; called by muse, mutect2, varscan2
- CIPC | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100694425; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | catalogued as rs752250702; called by mutect2, varscan2
- CLCNKB | c.335A>G p.Q112R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV100990198; called by muse, mutect2, varscan2
- CLEC4E | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778305486, COSV55227338; called by muse, mutect2, varscan2
- CLGN | c.1522del p.T508Pfs*12 | Frame Shift Del (DEL) | VAF 15/76 reads (20%) | catalogued as rs1217577246; called by mutect2, pindel, varscan2
- CLINT1 | c.1457T>C p.L486P | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99753556; called by muse, mutect2, varscan2
- CLIP2 | c.2761C>A p.R921S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99791133, COSV99792397; called by muse, mutect2, varscan2
- CLOCK | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.898); catalogued as COSV100011639; called by muse, mutect2, varscan2
- CLP1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100239726; called by muse, varscan2
- CLP1 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs752132257, COSV57054362; called by muse, varscan2
- CLP1 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as rs762162042, COSV57055139; called by muse, mutect2, varscan2
- CLVS2 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); catalogued as COSV51561020; called by muse, mutect2, varscan2
- CNPPD1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV99811408; called by muse, mutect2
- CNTN1 | c.2921T>C p.V974A | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100751041; called by muse, mutect2, varscan2
- CNTN4 | c.1249A>G p.T417A | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.403); catalogued as COSV100638913; called by muse, mutect2, varscan2
- CNTNAP4 | c.2138G>A p.G713E | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV56695004; called by muse, mutect2, varscan2
- CNTNAP5 | c.3055A>G p.T1019A | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV101443137; called by muse, mutect2, varscan2
- COA6 | c.181del p.A61Pfs*9 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | catalogued as rs1161604507; called by mutect2, pindel, varscan2
- COL14A1 | c.3556G>A p.A1186T | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs775543009, COSV52846651; called by muse, mutect2, varscan2
- COL22A1 | c.4619A>G p.E1540G | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV100276773; called by muse, mutect2, varscan2
- COL6A6 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.239); catalogued as rs746030029, COSV100649948, COSV62023613, COSV62033874; called by muse, mutect2, varscan2
- COL7A1 | c.1837C>T p.R613* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as rs759634066, CM070882, COSV100095333; called by muse, mutect2, varscan2
- COL8A1 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.954); catalogued as COSV53737257; called by muse, mutect2, varscan2
- COL8A2 | c.668del p.G223Vfs*14 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as COSV57443421; called by mutect2, pindel
- COL9A1 | c.2018G>A p.G673D | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100294214, COSV57883496; called by muse, mutect2
- COL9A2 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs369221204; called by muse, mutect2, varscan2
- COPA | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99614868; called by muse, mutect2, varscan2
- COQ8A | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs142894121; called by muse, mutect2, varscan2
- CPEB1 | c.1229G>A p.R410Q (on ENST00000617958; = p.R350Q on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); catalogued as rs1018099950, COSV99917499; called by muse, mutect2, varscan2
- CPEB2 | c.2758G>T p.G920C | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99470051; called by muse, mutect2, varscan2
- CPNE6 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV53743098; called by muse, mutect2, varscan2
- CPSF2 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); catalogued as rs1178072840, COSV100102630; called by muse, mutect2, varscan2
- CSMD3 | c.10588G>A p.A3530T (on ENST00000297405 / NM_001363185.1; = p.A3361T on NM_052900.3) | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs750533886, COSV52243421; called by muse, mutect2, varscan2
- CSNK1G2 | c.223A>G p.K75E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV99729659; called by muse, mutect2, varscan2
- CTDSP1 | c.320A>G p.K107R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV99811884; called by muse, mutect2, varscan2
- CTSG | c.763del p.L255Cfs*3 | Frame Shift Del (DEL) | VAF 30/154 reads (19%) | catalogued as rs764116259; called by mutect2, pindel, varscan2
- CTTNBP2NL | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV99599828; called by muse, mutect2, varscan2
- CUBN | c.9311C>T p.T3104I | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV100912198; called by muse, mutect2, varscan2
- CUBN | c.6941T>C p.L2314S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100912199; called by muse, mutect2, varscan2
- CUEDC1 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs535055874, COSV100804680; called by muse, mutect2, varscan2
- CUL9 | c.3299A>G p.E1100G | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99334939; called by muse, mutect2, varscan2
- CWH43 | c.317T>C p.V106A | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV99892957; called by muse, mutect2, varscan2
- CYBB | c.304A>G p.K102E | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101059693; called by muse, mutect2, varscan2
- CYC1 | c.893T>C p.L298P | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV100010257; called by muse, mutect2, varscan2
- CYLC2 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs199562230; called by muse, mutect2, varscan2
- CYP11A1 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as rs916391071, COSV99165920; called by muse, mutect2, varscan2
- CYP2C8 | c.667A>G p.I223V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100987890; called by muse, mutect2, varscan2
- CYSTM1 | c.170A>C p.E57A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.287); catalogued as COSV99944878; called by muse, mutect2, varscan2
- DCAF10 | c.1133A>T p.E378V | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99647593; called by muse, mutect2
- DCAF7 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100177575; called by muse, mutect2, varscan2
- DCTD | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs766885547, COSV100830103; called by muse, mutect2, varscan2
- DCUN1D2 | c.155A>G p.H52R | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV100215098; called by muse, mutect2
- DDB1 | c.3194T>C p.V1065A | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100074360; called by muse, mutect2, varscan2
- DDB1 | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 21/94 reads (22%) | catalogued as COSV100074361; called by muse, mutect2, varscan2
- DDI2 | c.183G>T p.L61F | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100197477; called by muse, mutect2
- DDX58 | c.378T>G p.D126E | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV101152543; called by muse, mutect2, varscan2
- DEFB119 | c.175T>C p.S59P | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV53621361, COSV99489118; called by muse, mutect2, varscan2
- DEPTOR | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV53822840; called by muse, mutect2, varscan2
- DERL3 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as rs769361729, COSV51956140; called by mutect2, varscan2
- DGKE | c.76A>G p.T26A | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs375106157; called by muse, mutect2, varscan2
- DGKK | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs782206353, COSV101052905; called by muse, mutect2, varscan2
- DGLUCY | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99824074; called by muse, mutect2, varscan2
- DHRS2 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.741); catalogued as rs754590049, COSV99158827; called by muse, mutect2, varscan2
- DHX36 | c.460del p.M154Cfs*27 | Frame Shift Del (DEL) | VAF 18/87 reads (21%) | catalogued as rs373108427; called by mutect2, varscan2
- DHX40 | c.1072A>G p.R358G | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.551); catalogued as COSV99232776; called by muse, mutect2
- DHX57 | c.2195del p.L732Wfs*7 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as rs749610132; called by mutect2, varscan2
- DHX9 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as COSV62358884; called by mutect2, varscan2
- DIP2B | c.4060C>T p.R1354C | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758508881, COSV99998041; called by muse, mutect2, varscan2
- DIS3 | c.2032del p.I678Ffs*59 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs771690280; called by mutect2, varscan2
- DISC1 | c.2132G>T p.R711M | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.416); catalogued as COSV100790241; called by muse, mutect2
- DKK2 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.288); catalogued as rs1366887020, COSV99568057; called by muse, mutect2, varscan2
- DLEC1 | c.1174-2A>G p.X392_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100341670; called by muse, mutect2, varscan2
- DLG2 | c.1675G>T p.G559* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | catalogued as COSV99713161; called by muse, mutect2, varscan2
- DLG2 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs749744948, COSV54638303; called by muse, mutect2, varscan2
- DMD | c.9601del p.T3201Lfs*82 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as CD992501; called by mutect2, varscan2
- DMTN | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV99741496; called by muse, mutect2, varscan2
- DMTN | c.799A>C p.T267P | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as COSV99741501; called by muse, mutect2, varscan2
- DNAH1 | c.6920A>G p.Q2307R | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101324954; called by muse, mutect2, varscan2
- DNAH12 | c.276del p.G93Dfs*7 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs751671358; called by mutect2, varscan2
- DNAH17 | c.8176T>C p.F2726L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.786); catalogued as rs187665247; called by muse, mutect2, varscan2
- DNAH8 | c.3253C>T p.R1085* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as rs760107925, COSV59447426; called by muse, mutect2, varscan2
- DNAJC21 | c.1052A>C p.E351A | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as COSV100331298; called by muse, mutect2, varscan2
- DNASE1L3 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs747122870, COSV100568613; called by muse, mutect2, varscan2
- DNMT3B | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.021); catalogued as COSV99140540; called by mutect2, varscan2
- DOCK3 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.275); catalogued as rs758629699, COSV99809766; called by muse, mutect2, varscan2
- DOCK6 | c.3958C>T p.R1320W | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs754447735, COSV99624964; called by muse, mutect2, varscan2
- DOCK6 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as rs1381761927, COSV99370876; called by muse, mutect2, varscan2
- DOCK8 | c.3301T>G p.C1101G | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV101209831; called by muse, mutect2, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | catalogued as rs35482889; called by mutect2, varscan2
- DPYS | c.422A>G p.Q141R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100679342; called by muse, mutect2, varscan2
- DPYSL2 | c.901T>G p.F301V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV100233647; called by muse, mutect2, varscan2
- DPYSL3 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV100574938; called by muse, mutect2, varscan2
- DROSHA | c.3454T>G p.S1152A | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.193); catalogued as COSV100757511; called by muse, mutect2, varscan2
- DROSHA | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1032572786, COSV60774677; called by muse, mutect2, varscan2
- DRP2 | c.1784T>C p.L595P | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871820; called by muse, mutect2, varscan2
- DSC1 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780160984, COSV99937313; called by muse, mutect2, varscan2
- DSCAM | c.4931G>A p.R1644Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.728); catalogued as rs756021849, COSV68020300; called by muse, mutect2, varscan2
- DSCAML1 | c.2048A>G p.D683G (on ENST00000321322; = p.D623G on NM_020693.4) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs1369780508, COSV100354975; called by muse, mutect2, varscan2
- DSPP | c.329A>T p.N110I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.673); catalogued as COSV99216700; called by muse, mutect2, varscan2
- DUOX2 | c.3821T>C p.V1274A | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV101199606; called by muse, mutect2, varscan2
- DUOXA1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as rs770239459, COSV50993161; called by muse, mutect2, varscan2
- DUSP5 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100851839; called by muse, mutect2
- DVL2 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.784); catalogued as rs1282730801, COSV50035698; called by muse, mutect2, varscan2
- DYNC1H1 | c.11299A>G p.I3767V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100794588; called by muse, mutect2, varscan2
- EFL1 | c.1389G>T p.E463D | Missense Mutation (SNP) | VAF 50/181 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV99186457; called by muse, mutect2, varscan2
- EGFLAM | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.732); catalogued as rs200502241; called by muse, mutect2, varscan2
- EIF2AK4 | c.3046C>T p.H1016Y | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV99774220; called by muse, mutect2, varscan2
- EIF4A1 | c.335T>G p.L112W | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99548770; called by muse, mutect2, varscan2
- EIF5B | c.149del p.K50Sfs*10 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs749961066, COSV56813566; called by mutect2, varscan2
- EIF5B | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs767626569, COSV99176871; called by muse, mutect2, varscan2
- ELAC2 | c.1988A>G p.Y663C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs781379178, COSV99310217; called by muse, mutect2, varscan2
- ELMO3 | c.2104C>T p.R702W (on ENST00000652269; = p.R649W on NM_024712.5) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as rs753617002, COSV100440689; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 45/140 reads (32%) | catalogued as rs766700925; called by mutect2, varscan2
- EN1 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV54632517, COSV99727341; called by muse, mutect2, varscan2
- ENAH | c.1727A>C p.E576A (on ENST00000366844 / NM_001008493.3; = p.E555A on NM_018212.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99490204; called by muse, mutect2, varscan2
- ENDOU | c.1165T>C p.W389R (on ENST00000422538 / NM_001172439.2; = p.W348R on NM_006025.4) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99139286; called by muse, mutect2, varscan2
- ENGASE | c.1638del p.T547Pfs*14 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs759157900, COSV56136050; called by mutect2, pindel, varscan2
- EP400 | c.1952C>A p.P651H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV57786885; called by muse, mutect2, varscan2
- EPHA10 | c.850+1G>A p.X284_splice (on ENST00000373048 / NM_001099439.2; = p.G284D on NM_173641.2) | Splice Site (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100139801; called by muse, mutect2, varscan2
- EPHA3 | c.2496+4_2496+7del p.X832_splice | Splice Site (DEL) | VAF 16/89 reads (18%) | catalogued as rs1326357030; called by mutect2, pindel, varscan2
- EPHA5 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs749830045, COSV56645016; called by muse, mutect2, varscan2
- EPHA7 | c.1802A>C p.K601T | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.46); catalogued as COSV65177734; called by muse, mutect2, varscan2
- EPHB3 | c.1913T>C p.V638A | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100382850; called by muse, mutect2, varscan2
- EPHB6 | c.2099T>C p.V700A | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100844163; called by muse, mutect2, varscan2
- EPS8L1 | c.2017C>T p.R673W (on ENST00000201647 / NM_133180.3; = p.R546W on NM_017729.3) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as rs369284202; called by muse, mutect2, varscan2
- ERCC6L2 | c.826A>G p.R276G | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV99998348; called by muse, mutect2, varscan2
- ERGIC3 | c.532A>C p.T178P | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.588); catalogued as COSV99650164; called by muse, mutect2, varscan2
- ERICH3 | c.4033G>A p.G1345R | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.086); catalogued as rs867202707, COSV100443623; called by muse, mutect2, varscan2
- ERV3-1 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs377655142; called by muse, mutect2, varscan2
- ERV3-1 | c.473C>A p.T158N | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV99275262; called by muse, mutect2, varscan2
- ESCO2 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100533146; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs775950025; called by mutect2, varscan2
- ETAA1 | c.1294A>G p.T432A | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1265729278, COSV55472094, COSV55474604; called by muse, mutect2, varscan2
- ETV5 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs779639231, COSV60501408; called by muse, mutect2, varscan2
- EVC | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.689); catalogued as rs376440801; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EVI2A | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1437070936, COSV99907507; called by muse, mutect2, varscan2
- EXOC8 | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); catalogued as COSV99149501; called by muse, mutect2, varscan2
- EZH1 | c.768-2A>G p.X256_splice | Splice Site (SNP) | VAF 6/31 reads (19%) | catalogued as COSV101331345; called by muse, mutect2, varscan2
- F2 | c.1637A>G p.D546G | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100319374; called by muse, mutect2, varscan2
- FAM111B | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs375744577, COSV59112727; called by muse, mutect2, varscan2
- FAM117B | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV100287269; called by muse, mutect2, varscan2
- FAM135B | c.3578G>A p.R1193Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs761090729, COSV99420236; called by muse, mutect2, varscan2
- FAM234A | c.1294T>C p.S432P | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99395677; called by muse, mutect2
- FAM43A | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs763389184, COSV61672908; called by muse, mutect2, varscan2
- FAM47A | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1362470386, COSV100649767; called by muse, mutect2, varscan2
- FANCD2 | c.4052C>T p.T1351M | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.105); catalogued as rs775898191, COSV55046198; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FARSB | c.1595del p.G532Dfs*3 | Frame Shift Del (DEL) | VAF 32/135 reads (24%) | catalogued as COSV56049129; called by mutect2, pindel, varscan2
- FBN2 | c.7659del p.F2554Lfs*57 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | catalogued as rs748600284, COSV99331968; called by pindel, varscan2
- FBXL2 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs759723075, COSV52144175; called by muse, mutect2, varscan2
- FCN1 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV100878802, COSV100878835; called by muse, mutect2
- FCRLB | c.1151T>G p.L384R | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100396106; called by muse, mutect2, varscan2
- FES | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100182797; called by muse, mutect2, varscan2
- FEZF2 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51864233, COSV99334542; called by muse, mutect2, varscan2
- FGFR3 | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99600787; called by muse, mutect2, varscan2
- FHOD1 | c.3323T>C p.M1108T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs757132766, COSV99263897; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FLAD1 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as rs566351390, COSV99422174; called by muse, mutect2, varscan2
- FLG | c.1016A>G p.H339R | Missense Mutation (SNP) | VAF 78/263 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as rs1177012271, COSV100910844; called by muse, mutect2, varscan2
- FLG2 | c.2155T>C p.F719L | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.081); catalogued as rs369031792; called by muse, mutect2
- FLNA | c.3187G>A p.A1063T | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100774349; called by muse, mutect2, varscan2
- FLT3 | c.1184A>G p.K395R | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99607740; called by muse, mutect2, varscan2
- FMNL2 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs369392464; called by muse, varscan2
- FMO3 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs145526965, COSV100882415; called by muse, mutect2, varscan2
- FMO4 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 81/298 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV100882032; called by muse, mutect2, varscan2
- FNDC11 | c.910A>C p.T304P | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100918761; called by muse, mutect2, varscan2
- FNDC3A | c.1373T>C p.V458A (on ENST00000492622 / NM_001079673.2; = p.V402A on NM_014923.5) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs1485872871, COSV101256649; called by muse, mutect2, varscan2
- FOCAD | c.2375G>A p.G792E | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100620122; called by muse, mutect2
- FOXD4 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV100070512; called by muse, mutect2, varscan2
- FOXE1 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as COSV64300258; called by muse, mutect2, varscan2
- FOXK2 | c.1548G>T p.Q516H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs758838938, COSV100081864; called by muse, mutect2, varscan2
- FRAS1 | c.2452G>T p.A818S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.97); catalogued as COSV99349032; called by muse, mutect2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRMPD4 | c.3650C>T p.S1217L | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101042319; called by muse, mutect2, varscan2
- FRY | c.7021G>A p.G2341R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374001727; called by muse, mutect2, varscan2
- FZD1 | c.1418T>C p.L473P | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99842402; called by muse, mutect2, varscan2
- FZD8 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.189); catalogued as rs768002036, COSV65968378; called by muse, mutect2, varscan2
- GAR1 | c.173T>G p.F58C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99901863; called by muse, mutect2, varscan2
- GARS1 | c.2220A>C p.*740Cext*4 | Nonstop Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV101220007; called by muse, mutect2, varscan2
- GAS2 | c.907T>G p.S303A | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99534788; called by muse, mutect2, varscan2
- GAS6 | c.449del p.G150Afs*49 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | catalogued as rs773341392; called by mutect2, varscan2
- GATA3 | c.1262C>A p.P421Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60515507, COSV60517246, COSV60518853; called by muse, mutect2, varscan2
- GBA | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.834); catalogued as rs146774384; called by muse, mutect2
- GCN1 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as rs777505168, COSV56104714; called by muse, mutect2, varscan2
- GDF7 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.49); catalogued as rs1212242798, COSV99693999; called by muse, mutect2, varscan2
- GDPD3 | c.19T>C p.Y7H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV99531323; called by muse, mutect2, varscan2
- GEMIN4 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs370389257; called by muse, mutect2, varscan2
- GIGYF1 | c.2711A>C p.Q904P | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV99308928; called by muse, mutect2, varscan2
- GIPR | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs191937467; called by muse, mutect2, varscan2
- GJA5 | c.139del p.D47Mfs*112 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | catalogued as rs782528459, COSV54784545; called by mutect2, pindel, varscan2
- GJD2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV99290594; called by muse, mutect2, varscan2
- GJD4 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as rs1347303151, COSV58703453; called by muse, mutect2, varscan2
- GLDN | c.1604G>A p.G535D | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100117538; called by muse, mutect2, varscan2
- GLI2 | c.3376C>T p.P1126S (on ENST00000361492 / NM_001374353.1; = p.P1143S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs770059172, COSV100082568; called by muse, mutect2, varscan2
- GLIS3 | c.1274G>T p.R425M | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100173445; called by muse, mutect2, varscan2
- GLIS3 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs759183029, COSV100173446, COSV60938063; called by muse, mutect2, varscan2
- GLRA2 | c.127T>A p.S43T | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.483); catalogued as COSV99490414; called by muse, mutect2, varscan2
- GMPS | c.192A>G p.I64M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.271); catalogued as COSV99902942; called by muse, mutect2, varscan2
- GNGT1 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as rs532358490, COSV50352636; called by muse, mutect2, varscan2
- GOLGA2 | c.1069A>G p.M357V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs758084594, COSV101363078; called by muse, mutect2, varscan2
- GOLGB1 | c.788A>G p.E263G | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100510413; called by muse, mutect2, varscan2
- GON4L | c.5773C>T p.R1925W | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs781420905, COSV99673628; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | catalogued as rs370114090; called by mutect2, varscan2
- GPR142 | c.1220C>T p.T407M | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141197422; called by muse, mutect2, varscan2
- GPR146 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781755519, COSV52466374; called by muse, mutect2
- GPR162 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.761); catalogued as COSV50597241; called by muse, mutect2, varscan2
- GPR3 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.567); catalogued as COSV64995320; called by muse, mutect2
- GPR68 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV53175959; called by muse, mutect2
- GPRIN1 | c.171del p.R58Gfs*78 | Frame Shift Del (DEL) | VAF 29/84 reads (35%) | catalogued as rs765009644; called by mutect2, pindel, varscan2
- GRAMD1C | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV100822796; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 40/92 reads (43%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIP1 | c.2887C>T p.H963Y (on ENST00000359742 / NM_001379345.1; = p.H911Y on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.242); catalogued as rs1370679675, COSV99668407; called by muse, mutect2, varscan2
- GSTM4 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 103/380 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs766374788, COSV100263999; called by muse, mutect2, varscan2
- GSX2 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100482505; called by muse, mutect2
- GTF2H1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs139886224; called by muse, mutect2, varscan2
- GTF3C1 | c.2299del p.S767Vfs*7 | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | catalogued as rs1231771183; called by mutect2, pindel, varscan2
- GTF3C3 | c.1796G>A p.S599N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99826534; called by muse, mutect2, varscan2
- GTPBP2 | c.920T>C p.L307P | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100199862; called by muse, mutect2, varscan2
- GTSE1 | c.1929T>C p.A643= | Splice Region (SNP) | VAF 38/146 reads (26%) | catalogued as COSV101483191; called by muse, mutect2, varscan2
- GTSF1L | c.363del p.P122Lfs*50 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | catalogued as rs1568892529; called by mutect2, pindel, varscan2
- GUCY1A1 | c.1052G>T p.R351M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs776867022, COSV99637284; called by muse, mutect2, varscan2
- GYS1 | c.1206G>T p.R402S | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as COSV99620514; called by muse, mutect2, varscan2
- H1-2 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as rs761753866, COSV59193105; called by muse, mutect2, varscan2
- H2BC5 | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.315); catalogued as COSV99175225; called by muse, mutect2, varscan2
- H3-3A | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); catalogued as COSV100831238; called by muse, mutect2, varscan2
- H4C6 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as rs1163383503, COSV66685505; called by muse, mutect2, varscan2
- HDAC4 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.311); catalogued as rs746612197, COSV61862787; called by muse, mutect2, varscan2
- HERC5 | c.1812del p.F604Lfs*2 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | catalogued as rs1256699530; called by mutect2, pindel, varscan2
- HEY2 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV100856328; called by muse, mutect2, varscan2
- HIC2 | c.481dup p.R161Pfs*40 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as rs745918762; called by mutect2, varscan2
- HIVEP3 | c.802A>G p.I268V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as COSV99911714; called by muse, mutect2, varscan2
- HLA-B | c.626dup p.T211Dfs*10 | Frame Shift Ins (INS) | VAF 38/126 reads (30%) | catalogued as rs748204482, COSV69520417; called by mutect2, pindel, varscan2
- HLA-DRA | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs530789959, COSV66622719; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPC | c.452G>A p.R151Q (on ENST00000420743; = p.R138Q on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100192924, COSV60146091; called by muse, mutect2
- HNRNPM | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV55313340; called by muse, mutect2, varscan2
- HS6ST3 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1226165605, COSV100940109; called by muse, mutect2
- HSP90AB1 | c.112A>T p.I38F | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100806981; called by muse, varscan2
- HSPA1A | c.1719G>T p.K573N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV100989341; called by muse, mutect2, varscan2
- HUWE1 | c.4716G>T p.K1572N | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); catalogued as COSV99470955; called by muse, mutect2, varscan2
- IARS2 | c.397A>G p.K133E | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100228135; called by muse, mutect2, varscan2
- IARS2 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373578830; called by muse, mutect2, varscan2
- ICE1 | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56820647, COSV99663990; called by muse, mutect2, varscan2
- IFNE | c.277A>G p.R93G | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.105); catalogued as COSV100438753; called by muse, mutect2, varscan2
- IGDCC3 | c.1676G>A p.R559H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as rs757578690, COSV100030838; called by muse, mutect2, varscan2
- IGSF9B | c.3071C>T p.T1024M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs762381409, COSV58066767; called by muse, mutect2, varscan2
- IL17D | c.293T>A p.I98N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1224733644, COSV100513752; called by muse, mutect2, varscan2
- IL21R | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.64); catalogued as COSV61969343; called by muse, mutect2
- IL6R | c.148del p.V50* | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | catalogued as rs770415570, COSV59817362; called by mutect2, pindel, varscan2
- INAVA | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as rs760768222, COSV100949898, COSV100949982; called by muse, mutect2
- INPP5B | c.1574T>C p.L525P (on ENST00000373023; = p.L445P on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100886395; called by muse, mutect2, varscan2
- INPP5D | c.548C>T p.A183V (on ENST00000445964 / NM_001017915.3; = p.A182V on NM_005541.5) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.355); catalogued as COSV100856551; called by muse, mutect2, varscan2
- INTS1 | c.2857C>T p.R953C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1487957316, COSV67177771; called by muse, mutect2, varscan2
- INTS6 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs1261763323, COSV100246925, COSV100247303; called by muse, mutect2
- IPMK | c.276+1G>A p.X92_splice | Splice Site (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100880237; called by muse, mutect2, varscan2
- IRX5 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100315665; called by muse, mutect2, varscan2
- ITGA11 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201514289, COSV59875387; called by muse, mutect2, varscan2
- ITGA4 | c.1249A>G p.R417G | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as COSV99275848; called by muse, mutect2, varscan2
- ITGAD | c.2546C>A p.P849H | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV101210360; called by muse, mutect2, varscan2
- ITGB4 | c.3606G>T p.Q1202H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99563534; called by muse, mutect2, varscan2
- ITIH5 | c.2353G>A p.G785R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV99903926; called by muse, mutect2, varscan2
- ITM2A | c.5T>C p.V2A | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV100964422, COSV100964493; called by muse, mutect2
- ITPR1 | c.5428G>A p.D1810N (on ENST00000354582; = p.D1755N on NM_002222.7) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); catalogued as rs1045543092, COSV100229971; called by muse, mutect2, varscan2
- JAK1 | c.1859T>C p.I620T | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV100691217; called by muse, mutect2, varscan2
- JPH1 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs766321457, COSV100646455; called by muse, mutect2, varscan2
- JUP | c.782A>C p.K261T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100159372; called by muse, mutect2, varscan2
- KALRN | c.4250G>T p.R1417M | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53751943, COSV53759115; called by muse, mutect2, varscan2
- KARS1 | c.890G>T p.R297I | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100093819, COSV56692947; called by muse, mutect2, varscan2
- KAT6A | c.2830del p.V944Lfs*15 | Frame Shift Del (DEL) | VAF 33/216 reads (15%) | catalogued as COSV55906332; called by mutect2, pindel, varscan2
- KBTBD7 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV101068052; called by muse, mutect2, varscan2
- KCND2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 41/151 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV100474117; called by muse, varscan2
- KCNH5 | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100525622; called by muse, mutect2, varscan2
- KCNK17 | c.503del p.G168Afs*61 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as COSV64685346; called by mutect2, pindel, varscan2
- KCNS1 | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs761018535, COSV100067084; called by muse, varscan2
- KCTD16 | c.1149del p.A384Lfs*20 | Frame Shift Del (DEL) | VAF 38/64 reads (59%) | catalogued as rs753765917, COSV72577101; called by mutect2, varscan2
- KDM4B | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99345770; called by muse, mutect2, varscan2
- KDM5A | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as COSV66990462, COSV66990880; called by muse, mutect2, varscan2
- KIAA1210 | c.4772C>T p.A1591V | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV101273954, COSV101274023; called by muse, mutect2, varscan2
- KIAA1586 | c.619del p.I207Lfs*17 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | catalogued as rs746314511; called by mutect2, varscan2
- KIAA1841 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV54375232; called by muse, mutect2, varscan2
- KIDINS220 | c.3904G>T p.G1302C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.495); catalogued as COSV56760061, COSV99875155; called by muse, mutect2, varscan2
- KIF15 | c.1545G>A p.M515I | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100392586; called by muse, mutect2, varscan2
- KIF1C | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as rs150280414; called by muse, varscan2
- KIF1C | c.2713A>G p.S905G | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV100296994; called by muse, mutect2, varscan2
- KIF21A | c.3194T>C p.L1065P (on ENST00000361418 / NM_001378440.1; = p.L1052P on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100735340; called by muse, mutect2, varscan2
- KIF26A | c.3805del p.R1269Gfs*7 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | catalogued as rs1458694083, COSV59464465; called by mutect2, pindel, varscan2
- KIF27 | c.2684C>T p.P895L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs777539862, COSV52829524; called by muse, mutect2, varscan2
- KIF5A | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54060777; called by muse, mutect2, varscan2
- KIFC2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs781565567, COSV100023614; called by muse, mutect2, varscan2
- KLHL1 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751336229, COSV64770566; called by mutect2, varscan2
- KLHL10 | c.772G>T p.V258F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV99509428; called by muse, mutect2, varscan2
- KLHL14 | c.980T>A p.V327D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100808696; called by muse, mutect2, varscan2
- KLHL18 | c.184T>C p.Y62H | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99230592; called by muse, mutect2, varscan2
- KLHL22 | c.1899G>T p.E633D | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.333); catalogued as COSV99839164; called by muse, mutect2, varscan2
- KLHL22 | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.745); catalogued as COSV100185859; called by muse, mutect2, varscan2
- KLHL4 | c.961C>A p.L321I | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV100909236; called by muse, mutect2, varscan2
- KLHL6 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs757613109, COSV100384379; called by mutect2, varscan2
- KLK1 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV100032571; called by muse, mutect2, varscan2
- KLK15 | c.388C>A p.R130S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.107); catalogued as COSV100032573, COSV56826168; called by muse, mutect2, varscan2
- KLRK1 | c.164del p.F55Sfs*7 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs756606329, COSV53699502; called by mutect2, varscan2
- KMT2B | c.2686C>A p.L896I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99719005; called by muse, mutect2, varscan2
- KMT2D | c.11063G>C p.G3688A | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as COSV99978367; called by muse, mutect2, varscan2
- KNDC1 | c.4196C>T p.A1399V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs946482636, COSV100463650; called by muse, mutect2, varscan2
- KRIT1 | c.845A>C p.K282T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV100388630; called by muse, mutect2, varscan2
- KRT23 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs1038708683, COSV52927136, COSV52927708; called by muse, mutect2, varscan2
- KRT33B | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs370317934; called by muse, mutect2, varscan2
- KRT74 | c.1082T>C p.L361P | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99977412; called by muse, mutect2, varscan2
- KRT85 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 26/123 reads (21%) | catalogued as COSV99225219; called by muse, mutect2, varscan2
- KSR2 | c.1949G>T p.S650I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100194356; called by muse, mutect2, varscan2
- L3MBTL2 | c.1346C>T p.T449I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99345717; called by muse, mutect2, varscan2
- LAMA3 | c.8263G>T p.G2755* (on ENST00000313654 / NM_198129.4; = p.G1146* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99334097, COSV99334140; called by muse, mutect2, varscan2
- LAMB2 | c.5290C>T p.R1764W | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1231737650, COSV59734700; called by muse, mutect2, varscan2
- LAMP3 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as COSV99660367; called by muse, mutect2, varscan2
- LANCL2 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs201797363, COSV54647557; called by muse, mutect2, varscan2
- LCT | c.377A>G p.Q126R | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV99918804; called by muse, mutect2, varscan2
- LILRA6 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.765); catalogued as rs751748933, COSV54432884, COSV54436661; called by muse, mutect2, varscan2
- LIMK2 | c.1597G>T p.G533W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100058061; called by muse, mutect2, varscan2
- LINGO2 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs778347323, COSV58061692; called by muse, mutect2, varscan2
- LINGO3 | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs753078425, COSV101347221; called by muse, mutect2, varscan2
- LLGL1 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1063682; called by muse, mutect2, varscan2
- LMAN2 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV100288274; called by muse, mutect2, varscan2
- LRCH1 | c.2024G>A p.R675H | Missense Mutation (SNP) | VAF 94/448 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs200528685, COSV100243354; called by muse, mutect2, varscan2
- LRFN3 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV99873218; called by muse, mutect2
- LRIG2 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100743039; called by muse, mutect2, varscan2
- LRIT2 | c.877T>C p.W293R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV100258523; called by muse, mutect2, varscan2
- LRP1B | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV67232748; called by muse, varscan2
- LRP2 | c.9178G>T p.G3060* | Nonsense Mutation (SNP) | VAF 21/94 reads (22%) | catalogued as COSV55557332, COSV99786890; called by muse, mutect2, varscan2
- LRP6 | c.2558G>A p.R853H | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.042); catalogued as rs572509429, COSV53794849; called by muse, mutect2, varscan2
- LRP8 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs150845542; called by muse, mutect2, varscan2
- LRRC19 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 37/84 reads (44%) | catalogued as COSV101195775; called by muse, mutect2, varscan2
- LRRC41 | c.400del p.S134Pfs*116 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as rs1557715031, COSV58440688; called by mutect2, pindel, varscan2
- LRRC66 | c.1312C>A p.P438T | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as COSV58633131; called by muse, mutect2, varscan2
- LRRC8C | c.1524del p.W509Gfs*13 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs762972819; called by mutect2, pindel, varscan2
- LRRC8C | c.2099del p.P700Lfs*35 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | catalogued as rs1557671997; called by mutect2, pindel, varscan2
- LRRK2 | c.62T>C p.V21A | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100109451; called by muse, mutect2, varscan2
- LTF | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs763164407, COSV99206734; called by muse, mutect2
- LVRN | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV100773360; called by muse, mutect2, varscan2
- LY75 | c.4235del p.K1412Rfs*2 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | catalogued as rs1301982151; called by mutect2, varscan2
- LYN | c.327del p.E110Kfs*15 | Frame Shift Del (DEL) | VAF 48/206 reads (23%) | catalogued as rs1266824391, COSV99066642; called by mutect2, pindel, varscan2
- LYST | c.3035del p.K1012Rfs*7 | Frame Shift Del (DEL) | VAF 20/89 reads (22%) | catalogued as rs1329068698; called by mutect2, pindel, varscan2
- MAB21L2 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1333690879, COSV100461969; called by muse, mutect2, varscan2
- MAP2K3 | c.862dup p.Q288Pfs*88 (on ENST00000342679 / NM_145109.3; = p.Q259Pfs*88 on NM_002756.4) | Frame Shift Ins (INS) | VAF 5/20 reads (25%) | catalogued as rs1444828088; called by mutect2, pindel, varscan2
- MAP2K7 | c.776T>C p.L259P | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101208991, COSV101209205; called by muse, mutect2, varscan2
- MAP3K19 | c.3763T>C p.C1255R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100208189; called by muse, mutect2, varscan2
- MAP3K2 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100789259; called by muse, mutect2, varscan2
- MAP3K4 | c.479del p.N160Mfs*8 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as COSV62334603; called by mutect2, varscan2
- MAP7D1 | c.68del p.P23Qfs*33 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as rs761388884; called by mutect2, pindel, varscan2
- MAP9 | c.1700dup p.E568Gfs*14 | Frame Shift Ins (INS) | VAF 12/57 reads (21%) | catalogued as rs1215313075; called by mutect2, varscan2
- MAPK7 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55189761; called by muse, mutect2, varscan2
- MAPKAPK2 | c.1121del p.K374Rfs*11 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as rs1553432912; called by mutect2, pindel, varscan2
- MARCHF7 | c.886del p.S296Hfs*9 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | catalogued as rs1383130845; called by mutect2, varscan2
- MATN3 | c.1159del p.T387Hfs*10 | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | catalogued as rs1203662025; called by mutect2, pindel, varscan2
- MBD1 | c.1105C>T p.R369C (on ENST00000269468 / NM_001323950.1; = p.R346C on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53998236; called by muse, mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 33/110 reads (30%) | catalogued as rs749738168; called by mutect2, varscan2
- MCF2 | c.780dup p.L261Ifs*6 | Frame Shift Ins (INS) | VAF 14/32 reads (44%) | catalogued as rs1440858020; called by mutect2, varscan2
- MCF2L | c.2755C>T p.R919C (on ENST00000375608; = p.R887C on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566875775, COSV56182733; called by muse, mutect2, varscan2
- MCM7 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1468156203, COSV100384733; called by muse, mutect2
- MEAF6 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV56163559; called by muse, mutect2, varscan2
- MED12 | c.2585G>A p.G862D | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100376565; called by muse, mutect2, varscan2
- MED13L | c.746del p.K249Rfs*23 | Frame Shift Del (DEL) | VAF 18/85 reads (21%) | catalogued as rs1566014158; called by mutect2, pindel, varscan2
- MEDAG | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100995226; called by muse, varscan2
- MEGF6 | c.2197G>A p.V733M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs374619419; called by muse, mutect2, varscan2
- MEIS1 | c.1095T>G p.H365Q | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV99714638; called by muse, mutect2, varscan2
- MEIS2 | c.331G>A p.G111R (on ENST00000561208 / NM_170675.5; = p.G98R on NM_002399.3) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV54938940; called by muse, mutect2, varscan2
- MERTK | c.1135A>C p.T379P | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.786); catalogued as COSV99774192; called by muse, mutect2, varscan2
- MEX3B | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61663636; called by muse, varscan2
- MFSD11 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs763350082, COSV60620942; called by muse, mutect2, varscan2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 16/85 reads (19%) | catalogued as rs769987847; called by mutect2, pindel, varscan2
- MIB1 | c.1933G>A p.V645I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.699); catalogued as rs747233793, COSV55087806; called by muse, mutect2, varscan2
- MIDEAS | c.106del p.Q36Sfs*6 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as COSV54098507; called by mutect2, pindel, varscan2
- MIER2 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.673); catalogued as rs770094709, COSV53397746, COSV99316095; called by muse, mutect2, varscan2
- MLH1 | c.207G>T p.R69S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99212350; called by muse, mutect2, varscan2
- MMP17 | c.1079A>G p.D360G | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV62178761; called by muse, mutect2, varscan2
- MMRN1 | c.3312del p.F1104Lfs*8 | Frame Shift Del (DEL) | VAF 27/98 reads (28%) | catalogued as rs1160529882; called by mutect2, varscan2
- MOK | c.313del p.I105Lfs*25 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | catalogued as rs753079987; called by mutect2, varscan2
- MORC3 | c.685A>G p.T229A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV101264862; called by muse, mutect2, varscan2
- MPO | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99832340; called by muse, mutect2, varscan2
- MPP2 | c.665G>A p.R222H (on ENST00000461854 / NM_001278372.2; = p.R198H on NM_005374.5) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs764787857, COSV52237607, COSV99290087; called by muse, mutect2, varscan2
- MPP6 | c.1195A>T p.I399F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99757283; called by muse, mutect2, varscan2
- MPV17 | c.278A>G p.Q93R | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM124846, COSV99274207; called by mutect2, varscan2
- MROH2B | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV101270569, COSV68183631; called by muse, mutect2
- MS4A13 | c.307-1G>A p.X103_splice | Splice Site (SNP) | VAF 14/49 reads (29%) | catalogued as COSV100981051, COSV65445522; called by muse, mutect2, varscan2
- MSH5 | c.1565T>G p.V522G | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV100994733; called by muse, mutect2, varscan2
- MSR1 | c.1139A>G p.E380G | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.883); catalogued as COSV100026726; called by muse, mutect2, varscan2
- MSRA | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV100412501; called by muse, mutect2, varscan2
- MST1R | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as rs774953632, COSV99617985; called by muse, mutect2, varscan2
- MSX1 | c.485del p.P162Qfs*55 | Frame Shift Del (DEL) | VAF 13/79 reads (16%) | catalogued as rs762477502; called by mutect2, pindel, varscan2
- MTA1 | c.458A>G p.Y153C | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100494962; called by muse, mutect2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs759847587; called by mutect2, varscan2
- MTFR2 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as rs141467777; called by muse, mutect2, varscan2
- MTHFR | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs753278299, COSV64879330; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTMR6 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as rs1177768356, COSV67807903; called by muse, mutect2, varscan2
- MTOR | c.3527C>T p.T1176M | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs557533784, COSV63877754; called by muse, mutect2, varscan2
- MUC16 | c.6731C>T p.A2244V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as COSV101198545; called by muse, mutect2, varscan2
- MUC16 | c.1426T>C p.S476P | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.31); catalogued as COSV101198546; called by muse, mutect2, varscan2
- MUS81 | c.194T>A p.I65N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV100353995; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 7/10 reads (70%) | catalogued as rs764857791; called by mutect2, varscan2
- MYCBP2 | c.5971T>C p.Y1991H (on ENST00000357337; = p.Y2029H on NM_015057.5) | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100629382; called by muse, mutect2
- MYH7B | c.3278G>A p.R1093H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768531311, COSV53425604; called by muse, mutect2, varscan2
- MYLIP | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100785917; called by muse, mutect2
- MYO10 | c.5123G>A p.G1708D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV99944844; called by muse, mutect2
- MYO15A | c.872A>G p.H291R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.051); catalogued as rs1396567000, COSV99231507; called by muse, mutect2, varscan2
- MYO19 | c.1373G>T p.G458V | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1179477563; called by muse, mutect2, varscan2
- MYO5A | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.85); catalogued as COSV100697380; called by muse, mutect2, varscan2
- MYO5C | c.5123C>T p.T1708I | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.185); catalogued as COSV99953159; called by muse, mutect2, varscan2
- MYOM1 | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1166475389, COSV99865657; called by muse, mutect2
- MYT1L | c.1417C>G p.L473V | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.163); catalogued as COSV101219251; called by muse, mutect2, varscan2
- NAA35 | c.1700del p.K567Rfs*6 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs770577267; called by mutect2, varscan2
- NANOS2 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58025206; called by muse, mutect2, varscan2
- NCF4 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs778347689, COSV50620479; called by muse, mutect2, varscan2
- NDUFA10 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.759); catalogued as rs557444462, COSV53152596; called by muse, mutect2, varscan2
- NELFB | c.1064A>G p.D355G | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV100546825; called by muse, mutect2, varscan2
- NEU3 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.648); catalogued as rs369919491, COSV53636877; called by muse, mutect2, varscan2
- NFIB | c.353T>C p.I118T | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101100255; called by muse, mutect2, varscan2
- NGEF | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 8/144 reads (6%) | catalogued as COSV99888285; called by muse, mutect2
- NID1 | c.2612C>T p.P871L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs200827911, COSV51626040, COSV99937112; called by muse, mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 20/91 reads (22%) | catalogued as rs145147241; called by mutect2, varscan2
- NIPSNAP2 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as rs760837804, COSV100436642; called by muse, mutect2, varscan2
- NISCH | c.4486C>T p.R1496C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1359997532, COSV58738486; called by muse, mutect2, varscan2
- NIT1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100919041, COSV63501315; called by muse, mutect2, varscan2
- NLGN4Y | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.286); catalogued as COSV100196449; called by muse, mutect2, varscan2
- NLRC4 | c.2369T>C p.L790P | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs202095832; called by muse, mutect2, varscan2
- NLRP13 | c.2958-1G>T p.X986_splice | Splice Site (SNP) | VAF 5/63 reads (8%) | catalogued as COSV100738071; called by muse, mutect2
- NLRP3 | c.361T>C p.Y121H | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100275438; called by muse, mutect2, varscan2
- NLRP3 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1041601343, COSV100275439; called by muse, mutect2, varscan2
- NLRP6 | c.1186A>G p.T396A | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV100380956; called by muse, mutect2, varscan2
- NLRP9 | c.2905dup p.I969Nfs*13 | Frame Shift Ins (INS) | VAF 18/73 reads (25%) | catalogued as rs765623160; called by mutect2, pindel, varscan2
- NOL12 | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1338793528, COSV100767130; called by muse, mutect2, varscan2
- NOL6 | c.2863C>T p.R955C | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as rs141680920; called by muse, mutect2, varscan2
- NOSIP | c.646A>G p.T216A | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0.037); catalogued as COSV100182155; called by muse, mutect2, varscan2
- NOSIP | c.235_237del p.K79del | In Frame Del (DEL) | VAF 82/292 reads (28%) | catalogued as rs751353745; called by pindel, varscan2
- NPIPB15 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV101465964; called by muse, varscan2
- NPR2 | c.2903G>A p.G968E | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756547227; called by muse, mutect2, varscan2
- NRG2 | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV99179967; called by muse, mutect2
- NTHL1 | c.568A>G p.K190E (on ENST00000219066; = p.K182E on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99526161; called by muse, mutect2, varscan2
- NTN1 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99432485; called by muse, mutect2
- NUBP1 | c.869C>A p.S290Y | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99296661; called by muse, mutect2, varscan2
- NUP107 | c.1682G>A p.G561E | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99971560; called by muse, mutect2, varscan2
- NUP153 | c.2141G>A p.G714D | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV100019928; called by muse, mutect2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs760869296; called by mutect2, varscan2
- OGFR | c.349T>C p.W117R | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99283812; called by muse, mutect2, varscan2
- OGT | c.1502G>A p.R501K | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as COSV101035212; called by muse, mutect2, varscan2
- OLFM2 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1449972198, COSV99321559, COSV99321595; called by muse, mutect2, varscan2
- OPA1 | c.739C>T p.R247C (on ENST00000361510 / NM_130837.3; = p.R211C on NM_130832.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs372957905; called by muse, mutect2, varscan2
- OR10A5 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.05); catalogued as COSV100203386; called by muse, mutect2, varscan2
- OR13C8 | c.465C>A p.D155E | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV100622942; called by muse, mutect2, varscan2
- OR1N2 | c.134A>G p.N45S | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV101031352; called by muse, mutect2, varscan2
- OR2AG2 | c.921del p.K307Nfs*? | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs761118518; called by mutect2, pindel
- OR2AT4 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100532288, COSV59408075; called by muse, mutect2, varscan2
- OR2M3 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs199968773, COSV71759103; called by muse, mutect2, varscan2
- OR2M5 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV100822750; called by muse, mutect2, varscan2
- OR2T12 | c.787C>A p.H263N | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100527596, COSV100528078; called by muse, mutect2, varscan2
- OR4N2 | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.019); catalogued as COSV100269433, COSV60051818; called by muse, mutect2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | catalogued as rs755413956; called by mutect2, varscan2
- OR52E8 | c.782T>C p.F261S | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1315955680, COSV101190048; called by muse, mutect2
- OR5H6 | c.77C>T p.T26I (on ENST00000642105; = p.T10I on NM_001005479.2) | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV101051749; called by muse, mutect2, varscan2
- OR5I1 | c.265T>A p.S89T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.952); catalogued as COSV100041247; called by muse, mutect2, varscan2
- OR5P3 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100103033; called by muse, mutect2
- OR5V1 | c.242T>C p.M81T | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV101011145; called by muse, mutect2, varscan2
- OR6B2 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99401244; called by muse, mutect2, varscan2
- OR6C75 | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV100595267, COSV58553459; called by muse, varscan2
- OR9K2 | c.978del p.K326Nfs*3 (on ENST00000305377; = p.K304Nfs*3 on NM_001005243.1) | Frame Shift Del (DEL) | VAF 21/88 reads (24%) | catalogued as rs1249976011; called by mutect2, pindel, varscan2
- OSR1 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1388802506, COSV55344623; called by muse, mutect2, varscan2
- OTUB1 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99734772; called by muse, mutect2
- P2RY8 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV101183952; called by muse, mutect2, varscan2
- PA2G4 | c.1117_1119del p.K373del | In Frame Del (DEL) | VAF 24/120 reads (20%) | catalogued as rs1174297940; called by pindel, varscan2
- PAK4 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as rs748636101, COSV100426387; called by muse, varscan2
- PAN2 | c.2593G>A p.G865R (on ENST00000425394 / NM_001127460.3; = p.G861R on NM_014871.5) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.173); catalogued as COSV99228141; called by muse, mutect2, varscan2
- PARP10 | c.1916C>A p.P639H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100477798; called by muse, mutect2, varscan2
- PATJ | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201550049, COSV57159083; called by muse, mutect2, varscan2
- PATZ1 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as COSV99315142; called by muse, mutect2
- PCCB | c.424T>C p.C142R | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99291132; called by muse, mutect2, varscan2
- PCDH9 | c.2974A>G p.S992G | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773838866, COSV100118922; called by muse, mutect2, varscan2
- PCDHA11 | c.1501C>A p.R501S | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs376574285; called by muse, mutect2, varscan2
- PCDHA13 | c.1430T>C p.V477A | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99165167; called by muse, varscan2
- PCDHA7 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.846); catalogued as COSV65342015; called by muse, mutect2, varscan2
- PCDHB11 | c.317T>C p.L106S | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99503809; called by muse, mutect2, varscan2
- PCDHB11 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV61309917; called by muse, mutect2, varscan2
- PCDHB16 | c.467A>G p.H156R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV99501369; called by muse, mutect2, varscan2
- PCDHB5 | c.1528G>A p.G510S | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50652564, COSV99167683; called by muse, mutect2, varscan2
- PCDHB6 | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV50706785; called by muse, mutect2, varscan2
- PCDHB7 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99176141; called by muse, mutect2, varscan2
- PCDHB7 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.072); catalogued as rs782813382, COSV99176145; called by muse, mutect2, varscan2
- PCDHB7 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.407); catalogued as COSV50755714; called by muse, mutect2, varscan2
- PCDHGA12 | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); catalogued as rs912037044, COSV99338542; called by muse, mutect2, varscan2
- PCDHGA7 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.15); catalogued as COSV99532790; called by mutect2, varscan2
- PCDHGB4 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99532791; called by muse, mutect2, varscan2
- PCSK5 | c.4246A>G p.K1416E | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV101377300; called by muse, mutect2, varscan2
- PDCD5 | c.294del p.V99* | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | catalogued as rs1373819281; called by mutect2, pindel, varscan2
- PDE10A | c.419C>A p.P140H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.866); catalogued as COSV100604624; called by muse, mutect2
- PDE1B | c.1392G>T p.Q464H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99226296; called by muse, varscan2
- PDE4D | c.2389C>T p.P797S (on ENST00000340635 / NM_001104631.2; = p.P661S on NM_006203.4) | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1295172715, COSV100401432; called by muse, varscan2
- PDE4DIP | c.4313T>C p.L1438P | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517248; called by muse, mutect2, varscan2
- PDGFA | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs777482095, COSV100627274; called by muse, mutect2, varscan2
- PDLIM5 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as rs761636570, COSV58752727; called by muse, mutect2, varscan2
- PDZD8 | c.1327G>C p.V443L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1336356388, COSV100559423; called by muse, mutect2, varscan2
- PDZRN4 | c.3070A>G p.T1024A (on ENST00000402685 / NM_001164595.2; = p.T766A on NM_013377.4) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV100113835; called by muse, mutect2, varscan2
- PEAR1 | c.1762T>C p.C588R | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99440785; called by muse, mutect2, varscan2
- PEAR1 | c.3012del p.G1005Afs*57 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | catalogued as rs750264783; called by mutect2, pindel, varscan2
- PEBP1 | c.252G>A p.W84* | Nonsense Mutation (SNP) | VAF 4/43 reads (9%) | catalogued as COSV99731820; called by muse, mutect2
- PER1 | c.2495G>A p.R832Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.119); catalogued as rs753761027, COSV57919323; called by muse, mutect2, varscan2
- PER2 | c.1753A>G p.S585G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV99611511; called by muse, mutect2, varscan2
- PEX6 | c.2317C>T p.L773F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99769571; called by muse, mutect2, varscan2
- PEX6 | c.1681del p.L561Sfs*58 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs1200299979; called by mutect2, pindel, varscan2
- PFKL | c.1295T>C p.V432A | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.391); catalogued as rs778200077, COSV100827019; called by muse, mutect2, varscan2
- PFKP | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1424918673, COSV101126689; called by muse, mutect2, varscan2
- PGBD1 | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV99459831; called by muse, mutect2, varscan2
- PHACTR2 | c.513dup p.S172Ifs*17 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs762386860; called by mutect2, pindel
- PHF8 | c.3100C>T p.R1034C (on ENST00000357988 / NM_001184896.1; = p.R998C on NM_015107.3) | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781843080, COSV57687258; called by muse, mutect2, varscan2
- PHOSPHO1 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV56801089; called by muse, mutect2, varscan2
- PIBF1 | c.1808A>G p.D603G | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as COSV100411284; called by muse, mutect2
- PIGO | c.2822C>T p.A941V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.171); catalogued as COSV99956457; called by muse, mutect2, varscan2
- PIK3AP1 | c.1972A>G p.T658A | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.302); catalogued as COSV100225571; called by muse, mutect2, varscan2
- PIK3R2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs768743781, COSV99717247; called by muse, mutect2, varscan2
- PIK3R4 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100768279; called by muse, mutect2, varscan2
- PITX3 | c.79C>A p.Q27K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV100892756; called by muse, mutect2, varscan2
- PIWIL2 | c.545del p.P182Rfs*23 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | catalogued as COSV63251312; called by mutect2, pindel, varscan2
- PKD1L1 | c.4941A>G p.I1647M | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV99218764; called by muse, mutect2, varscan2
- PKN3 | c.1953_1954insA p.H652Tfs*38 | Frame Shift Ins (INS) | VAF 16/68 reads (24%) | catalogued as COSV99403355; called by mutect2, pindel, varscan2
- PLA2G4C | c.120G>T p.E40D | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV100843858; called by muse, mutect2, varscan2
- PLBD1 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764137177, COSV99554286; called by muse, mutect2, varscan2
- PLCB4 | c.2420A>G p.K807R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.931); catalogued as COSV99594607; called by muse, mutect2, varscan2
- PLCG2 | c.3031G>A p.A1011T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100842101; called by muse, mutect2, varscan2
- PLD5 | c.326G>A p.R109Q (on ENST00000442594; = p.R47Q on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs749531675, COSV59160757; called by muse, mutect2, varscan2
- PLEC | c.2065G>A p.E689K (on ENST00000322810 / NM_201380.4; = p.E579K on NM_000445.5) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV100511682, COSV59648293; called by muse, mutect2, varscan2
- PLK2 | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV57108665; called by muse, varscan2
- PLOD2 | c.2114G>A p.G705D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99282441; called by muse, mutect2, varscan2
- PLPPR4 | c.275A>C p.D92A | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV100927038; called by muse, mutect2, varscan2
- PLXNA1 | c.3956T>C p.I1319T | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99302495; called by muse, mutect2, varscan2
- PLXNA3 | c.4079A>G p.D1360G | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100859829; called by muse, mutect2, varscan2
- PLXNB2 | c.5014G>A p.D1672N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs962147918, COSV100833883; called by muse, mutect2, varscan2
- PLXNB2 | c.4172G>A p.R1391H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1431309803, COSV100833884; called by muse, mutect2, varscan2
- PNLIPRP1 | c.697T>C p.F233L | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as COSV100724283; called by muse, mutect2, varscan2
- PNPLA5 | c.349G>T p.G117C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.571); catalogued as COSV99336507; called by muse, mutect2, varscan2
- PNPLA7 | c.3829G>A p.A1277T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.043); catalogued as rs375176295, COSV53004736, COSV99480257; called by muse, mutect2, varscan2
- POLQ | c.4289T>A p.L1430* | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as rs377402875; called by muse, varscan2
- POLR1A | c.4552G>A p.D1518N | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774906086, COSV55689421; called by muse, mutect2, varscan2
- POLR1C | c.447C>G p.N149K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as COSV99540530; called by muse, mutect2, varscan2
- POLR3H | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as rs776419185, COSV100519883; called by muse, mutect2, varscan2
- POMT1 | c.1148+2T>C p.X383_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100586155; called by muse, mutect2, varscan2
- POTEE | c.2057del p.K686Rfs*6 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs772047281; called by mutect2, varscan2
- POU3F3 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV100796839; called by muse, mutect2, varscan2
- PPARG | c.985A>G p.K329E (on ENST00000287820 / NM_015869.5; = p.K299E on NM_005037.7) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99826335; called by muse, mutect2, varscan2
- PPARGC1B | c.622T>C p.S208P | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100494548, COSV58526723; called by muse, mutect2, varscan2
- PPCDC | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100738804; called by muse, mutect2, varscan2
969 further variants in this file (570 protein-altering or splice-affecting, 361 silent, 38 other) are not listed here.
